CCDI case PBCRER — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4469e0b5-1da6-4cad-bb76-118b2c19f3c4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.7 years (252 days).

Biospecimens (3 samples)
- Sample 0DX8JR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX8JT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX8KK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
